Somatic mutation profile of tumor specimen 0DV14Z from CCDI case PBCMAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.3 years (99 days).
Specimen 0DV14Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ee98bc9-a29f-4599-b44f-cf490d55f4d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd002089-c1e1-48cc-821e-f4a272dd7b01

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 54/2286 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CAPRIN2 | c.2601+1G>A p.X867_splice | Splice Site (SNP) | VAF 37/1538 reads (2%) | called by muse, mutect2
- CEP250 | c.2238G>A p.Q746= | Silent (SNP) | VAF 142/1183 reads (12%) | called by muse, mutect2, varscan2
- MYO7A | c.5973G>A p.V1991= | Silent (SNP) | VAF 26/1016 reads (3%) | called by muse, mutect2
